Surgical pathology report (de-identified scan), TCGA case TCGA-19-1790, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-1790-01B (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS

A. RIGHT FRONTAL PARIETAL MASS T-10 POSTERIOR, B. RIGHT FRONTAL PARIETAL MASS T-10 ANTERIOR, BIOPSIES:

--MILDLY HYPERCELLULAR WHITE MATTER.

C. RIGHT FRONTAL PARIETAL MASS T0 ANTERIOR, D. RIGHT FRONTAL PARIETAL MASS T0 POSTERIOR, E. RIGHT FRONTAL PARIETAL MASS TM +10 ANTERIOR, F. RIGHT FRONTAL PARIETAL MASS T=10 POSTERIOR, BIOPSIES:

--GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

G. TUMOR FOR STUDY [REDACTED], REMOVAL:

--GLIOBLASTOMA MULTIFORME, SEE NOTE.

Note: Sections from both poles of the specimen show tumor.

H. #7 SUPERFICIAL CORTEX, BIOPSY:

--HYPERCELLULAR GRAY AND WHITE MATTER WITH REACTIVE FEATURES.

I. #5 CORE, REMOVAL:

--GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

J. #6 EDGE, BIOPSY:

--GLIOBLASTOMA MULTIFORME, SEE NOTE.

Note: The specimen contains both tumor and adjacent non-neoplastic tissue.

Electronically Signed Out By [REDACTED]

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consult Diagnosis

A,B. Touch Imprint and Microscopic: Gliosis.

C-F. Touch Imprint and Microscopic: Glioblastoma Multiforme.

Clinical History:

right frontal parietal brain mass. gbm vs lymphoma

Specimens Submitted As:

A:RIGHT FRONTAL PARIETAL MASS T-10 POSTERIOR

B:RIGHT FRONTAL PARIETAL MASS T-10 ANTERIOR

C:RIGHT FRONTAL PARIETAL MASS T0 ANTERIOR

D:RIGHT FRONTAL PARIETAL MASS T0 POSTERIOR

E:RIGHT FRONTAL PARIETAL MASS TM +10 ANTERIOR

F:RIGHT FRONTAL PARIETAL MASS T=10 POSTERIOR

G:TUMOR FOR STUDY [REDACTED]

H:#7 SUPERFICIAL CORTEX

I:#5 CORE

J:#6 EDGE

[page 2 of 2]
Gross Description:

A: Received fresh, for intraoperative consultation, labelled with the patient's name and number, are multiple fragments of gray-red, soft tissue which are irregularly-shaped and unoriented, 0.4 x 0.3 x 0.1 cm in aggregate. The portion of the tissue is frozen. The tissue is submitted in entirety in two cassettes.

B: Received fresh, for intraoperative consultation, labelled with the patient's name and number, is a fragment of gray-red, soft tissue which is irregularly-shaped and unoriented, 1.0 x 0.2 x 0.1 cm. A portion of the tissue is frozen. The tissue is submitted in entirety in two cassettes.

C: Received fresh, for intraoperative consultation, labelled with the patient's name and number, is a fragment of gray-red, soft tissue which is irregularly-shaped and unoriented, 0.5 x 0.2 x 0.2 cm. A portion of the tissue is frozen. The tissue is submitted in entirety in two cassettes.

D: Received fresh, for intraoperative consultation, labelled with the patient's name and number, is a fragment of gray-red, soft tissue which is irregularly-shaped and unoriented, 0.6 x 0.2 x 0.2 cm. A portion of the tissue is frozen. The tissue is submitted in entirety in two cassettes.

E: Received fresh, for intraoperative consultation, labelled with the patient's name and number, is a fragment of gray-red, soft tissue which is irregularly-shaped and unoriented, 0.5 x 0.3 x 0.2 cm. A portion of the tissue is frozen. The tissue is submitted in entirety in two cassettes.

F: Received fresh, for intraoperative consultation, labelled with the patient's name and number, is a fragment of gray-red, soft tissue which is irregularly-shaped and unoriented, 0.6 x 0.2 x 0.2 cm. A portion of the tissue is frozen. The tissue is submitted in entirety in two cassettes.

G: Received fresh, labelled with the patient's name, number and "tumor for study [REDACTED]", is a single fragment of tan-gray and red tissue measuring 2.4 x 1.7 x 1.0 cm. 10% of the specimen is sectioned from the area designated "top", 10% is sectioned from the area at the other end designated "bottom", 9% of the specimen is sectioned from the middle and divided among three cryo vials and snap frozen.

H: Received fresh, post fixed in formalin, labeled with the patient's name number, and "A-#7 super cortex", are multiple irregular opaque white to tan, soft, cerebriform tissue fragments measuring in aggregate 2.2 x 1.8 x 0.3 cm. Submitted in toto in one cassette.

I: Received fresh, post fixed in formalin, labeled with the patient's name and number, and "B-#5 perm core" are multiple irregular, opaque white to tan-brown, soft, cerebriform tissue fragments measuring in aggregate 3.1 x 2.7 x 0.6 cm. Submitted in toto in two cassettes.

J: Received fresh, post fixed in formalin, labeled with the patient's name and number, and "C-#6-perm edge", are multiple irregular, opaque white to tan-brown, soft, cerebriform tissue fragments measuring in aggregate 2.5 x 2.3 x 0.4 cm. Submitted in toto in two cassettes.

Summary of Cassettes:

Specimen	Label	Site
G	1	top
	2	bottom

Source: NCI Genomic Data Commons file 775116d5-c3a9-4812-af99-5c2d1b95ded2 (TCGA-19-1790.D9526D0F-5182-42D3-B73F-1FF9F38AEDE4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).